Somatic mutation profile of tumor specimen TCGA-30-1857-01A (aliquot TCGA-30-1857-01A-02W-0639-09) from TCGA case TCGA-30-1857, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.9 years (23,689 days).
Specimen TCGA-30-1857-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b4888fe-e8f9-485d-a0cf-a2ed0c499f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1857-10A (Blood Derived Normal), aliquot TCGA-30-1857-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faf7bb2e-0243-4e68-b0b8-346e6fc302b6

The open-access MAF lists 113 somatic variants for this specimen: 96 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 13, Frame Shift Del 11, Nonsense Mutation 5, Splice Site 4, Intron 3, In Frame Del 3, Splice Region 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs139400379, CM983442, COSV52942905; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs141257781, COSV99392721; called by muse, mutect2, varscan2
- ACTA1 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1558082103, CM105160, COSV64203229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM17 | c.2365G>C p.A789P | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.764); catalogued as COSV100175995; called by muse, mutect2
- ADGRF3 | c.2047G>A p.G683S (on ENST00000311519 / NM_001145168.1; = p.G484S on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.669); catalogued as COSV61049953; called by muse, mutect2, varscan2
- ANAPC1 | c.3640G>T p.A1214S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as COSV61975703; called by mutect2, varscan2
- ANGEL1 | c.1831T>C p.C611R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51872974; called by muse, mutect2, varscan2
- ARCN1 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99873373; called by muse, mutect2
- ASB11 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728919; called by muse, mutect2
- BCAN | c.2158G>C p.G720R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61256604; called by muse, mutect2, varscan2
- BDKRB1 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147649798; called by muse, mutect2, varscan2
- BNC1 | c.2540C>A p.S847Y | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61757212; called by muse, mutect2, varscan2
- BOD1L1 | c.5122G>C p.D1708H | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV50010674; called by muse, mutect2, varscan2
- BRCA1 | c.2398A>T p.K800* | Nonsense Mutation (SNP) | VAF 167/285 reads (59%) | catalogued as COSV58788741; called by muse, mutect2, varscan2
- BUD13 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374011576; called by muse, mutect2
- C1orf112 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs767191234, COSV53678219; called by muse, mutect2, varscan2
- CARMIL3 | c.1024A>T p.S342C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV57726139; called by muse, mutect2, varscan2
- CCDC27 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV53899802; called by muse, mutect2, varscan2
- CDH7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- CLSTN2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs766373799, COSV71719763; called by muse, mutect2, varscan2
- CMSS1 | c.416-1G>C p.X139_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV70436987, COSV70437852; called by muse, mutect2, varscan2
- COL23A1 | c.1272C>T p.G424= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV66789739; called by muse, mutect2
- DGKI | c.3170G>T p.G1057V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs776811524, COSV55947040; called by muse, mutect2, varscan2
- DHTKD1 | c.2750C>A p.T917N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as rs900369188, COSV53803193; called by muse, mutect2, varscan2
- DMRTC2 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54186480; called by mutect2, varscan2
- DNAH12 | c.820_822del p.K274del | In Frame Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs1176848392; called by pindel, varscan2
- DNAH17 | c.10955G>A p.R3652H | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs778024178, COSV67752998; called by muse, mutect2, varscan2
- DNAH7 | c.6121G>C p.V2041L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.718); catalogued as COSV100413670; called by muse, mutect2
- DNAJC12 | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV56547862, COSV99830735; called by muse, mutect2, varscan2
- DOCK4 | c.4234C>A p.H1412N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV70236065; called by muse, mutect2, varscan2
- DYNC2LI1 | c.551T>A p.I184N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53183210; called by muse, mutect2, varscan2
- EP400 | c.8553+3_8553+6del p.X2851_splice | Splice Site (DEL) | VAF 6/18 reads (33%) | catalogued as rs1565934609; called by mutect2, varscan2
- FASTKD3 | c.1440T>A p.G480= | Splice Region (SNP) | VAF 22/76 reads (29%) | catalogued as COSV52943018; called by muse, mutect2, varscan2
- FMNL3 | c.2339G>A p.S780N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99525510; called by muse, mutect2, varscan2
- FMNL3 | c.2338A>C p.S780R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99525517; called by muse, mutect2, varscan2
- FOXP2 | c.1676A>C p.H559P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63485056; called by muse, mutect2, varscan2
- HFM1 | c.3884-1G>A p.X1295_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as rs756777150, COSV54026068; called by muse, mutect2, varscan2
- HTR5A | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55282585, COSV55286142; called by muse, mutect2
- KCNA2 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100315801; called by muse, mutect2
- KDM4D | c.1130T>A p.L377H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV58634428; called by muse, mutect2, varscan2
- KIAA0100 | c.1667C>A p.S556* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV66492211; called by muse, mutect2, varscan2
- LCT | c.303C>G p.S101R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV51465969; called by muse, mutect2, varscan2
- LRP1 | c.6403C>T p.R2135* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as rs1555185557, COSV54509195; called by muse, mutect2, varscan2
- LRP10 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV62078147; called by muse, mutect2, varscan2
- LRP8 | c.2584G>C p.D862H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60097931, COSV60099664; called by muse, mutect2, varscan2
- LUC7L3 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53586628, COSV53586759; called by muse, mutect2, varscan2
- MAP3K6 | c.2867C>G p.P956R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.54); PolyPhen benign (0.077); catalogued as COSV58871402; called by muse, mutect2, varscan2
- MASP1 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as COSV61825929; called by muse, mutect2, varscan2
- MAST2 | c.5318G>A p.R1773K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.001); catalogued as COSV53106782; called by muse, mutect2, varscan2
- MTRF1 | c.870+1G>A p.X290_splice | Splice Site (SNP) | VAF 10/222 reads (5%) | catalogued as COSV101067432; called by muse, mutect2
- NF1 | c.244_247del p.Q83* | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as rs771115661; called by mutect2, pindel, varscan2
- OR10J1 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV101419774; called by muse, mutect2
- OR2J3 | c.760T>A p.F254I | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65848946; called by muse, mutect2, varscan2
- OR4D1 | c.924C>G p.C308W | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52124950; called by muse, mutect2, varscan2
- OXER1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV54310621; called by muse, mutect2, varscan2
- PEX11A | c.171A>T p.K57N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51531862; called by muse, mutect2, varscan2
- POP1 | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs370059328; called by muse, mutect2, varscan2
- PSG3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.829); catalogued as rs760433418, COSV59503934; called by muse, mutect2, varscan2
- PTPRJ | c.2875C>G p.R959G | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV101394334; called by muse, mutect2
- RELN | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as rs768432132, COSV58987031; called by muse, mutect2, varscan2
- RFC5 | c.977T>A p.I326N | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57477535; called by muse, mutect2, varscan2
- SBNO1 | c.3308T>A p.I1103K (on ENST00000420886; = p.I1102K on NM_018183.5) | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV99928638; called by muse, mutect2
- SCAI | c.1442A>G p.N481S (on ENST00000336505 / NM_001144877.3; = p.N504S on NM_173690.5) | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs762197125, COSV57176032; called by muse, mutect2, varscan2
- SIGLEC8 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.184); catalogued as COSV100367142; called by muse, mutect2, varscan2
- SLC4A3 | c.2732G>A p.R911H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093346, COSV56096053; called by muse, mutect2
- SLIT2 | c.4408G>T p.A1470S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.108); catalogued as COSV56569641; called by muse, mutect2, varscan2
- SNX15 | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57246623; called by muse, mutect2, varscan2
- TBXAS1 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs372058761, COSV54945453; called by muse, mutect2
- TENM2 | c.6591T>G p.N2197K (on ENST00000518659 / NM_001122679.2; = p.N1958K on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV69128443; called by muse, mutect2, varscan2
- TG | c.312A>T p.L104F | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55073584; called by muse, mutect2, varscan2
- TM4SF4 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as COSV59515564; called by muse, mutect2, varscan2
- UNC13C | c.6202A>T p.I2068F | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs750995078, COSV104391661, COSV52866180; called by muse, mutect2, varscan2
- VPS13B | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 63/145 reads (43%) | catalogued as COSV62018694; called by muse, mutect2, varscan2
- WAPL | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53934525; called by muse, mutect2, varscan2
- YARS1 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100993222; called by muse, mutect2
- ZFYVE26 | c.3079C>T p.L1027F | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV61327556; called by muse, varscan2
- ZFYVE26 | c.1039A>C p.K347Q | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100720031; called by muse, mutect2
- ZNF407 | c.2566G>T p.G856C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99994736; called by muse, mutect2
- ZNF502 | c.1586_1589del p.R529Ifs*20 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as rs754038717; called by mutect2, pindel, varscan2
- ZNF532 | c.2072T>G p.I691R | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV60172776; called by muse, mutect2, varscan2
- ZNF594 | c.1738A>G p.S580G | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.672); catalogued as COSV68385162; called by muse, mutect2, varscan2
- ZSWIM3 | c.1970A>T p.Q657L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV54846964; called by muse, mutect2, varscan2
- ARAP2 | c.441_442del p.P148Sfs*2 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | called by pindel, varscan2
- ARG2 | c.197_198del p.K66Rfs*14 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- CDK14 | c.329_330del p.K110Rfs*4 (on ENST00000380050 / NM_001287135.2; = p.K92Rfs*4 on NM_012395.3) | Frame Shift Del (DEL) | VAF 45/169 reads (27%) | called by mutect2, pindel, varscan2
- F5 | c.5359_5361del p.K1787del | In Frame Del (DEL) | VAF 28/158 reads (18%) | called by pindel, varscan2
- H4C2 | c.240_241del p.K80Nfs*47 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- LONP2 | c.768_785delinsC p.T257* | Frame Shift Del (DEL) | VAF 54/117 reads (46%) | called by pindel, varscan2*
- MAPKAPK3 | c.693_695del p.I231del | In Frame Del (DEL) | VAF 10/31 reads (32%) | called by pindel, varscan2
- RNF34 | c.162_163insTT p.T55Lfs*7 | Frame Shift Ins (INS) | VAF 17/93 reads (18%) | called by mutect2, varscan2
- RNF34 | c.165_174del p.E56Tfs*2 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel*, varscan2
- THRAP3 | c.2456_2457del p.F819Cfs*5 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- TRIM29 | c.359_377del p.T120Sfs*133 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- UAP1 | c.1019A>T p.D340V | Missense Mutation (SNP) | VAF 17/364 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2
- UBE4B | c.1595_1596del p.K532Rfs*7 (on ENST00000343090 / NM_001105562.3; = p.K403Rfs*7 on NM_006048.5) | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | called by mutect2, pindel, varscan2
- ADTRP | c.591C>T p.F197= | Silent (SNP) | VAF 76/327 reads (23%) | catalogued as COSV57642752; called by muse, mutect2, varscan2
- ALX1 | c.336G>A p.E112= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57492002; called by muse, mutect2, varscan2
- ARNT2 | c.441T>C p.D147= | Silent (SNP) | VAF 62/321 reads (19%) | catalogued as COSV57584413; called by muse, mutect2, varscan2
- FOXM1 | c.582A>C p.G194= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV61205820; called by muse, mutect2, varscan2
- GDF5 | c.1113G>A p.E371= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV65501007; called by muse, mutect2, varscan2
- MAP7D1 | c.219G>T p.G73= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV100294228; called by muse, mutect2
- MPL | c.789C>A p.I263= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100991269; called by muse, mutect2
- PCDH15 | c.5367A>T p.A1789= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV64689595; called by muse, mutect2, varscan2
- RNF41 | c.516G>T p.L172= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV100560107; called by muse, mutect2
- SIRT1 | c.477C>T p.S159= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs924253904, COSV53017915; called by muse, mutect2, varscan2
- TAS2R16 | c.321C>T p.V107= | Silent (SNP) | VAF 13/225 reads (6%) | called by muse, mutect2
- TTC29 | c.1380T>C p.R460= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV57274390; called by muse, mutect2, varscan2
- ZBTB5 | c.474C>G p.L158= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs746593739, COSV57039861; called by muse, mutect2, varscan2
- H2BP2 | n.1062-335G>C | Intron (SNP) | VAF 85/280 reads (30%) | called by muse, mutect2, varscan2
- NRP1 | c.1925-2328C>G | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as COSV55165113; called by muse, mutect2, varscan2
- SLC22A17 | n.1527G>T | RNA (SNP) | VAF 6/22 reads (27%) | catalogued as COSV52836935; called by muse, mutect2
- UGT1A6 | c.862-23459G>C | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100529695, COSV59387663; called by muse, mutect2, varscan2
